Gene-level copy-number profile of tumor specimen TCGA-A2-A0YH-01A from TCGA case TCGA-A2-A0YH, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 53.7 years (19,596 days).
Specimen TCGA-A2-A0YH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2d4e7bff-a4ec-4bf0-9925-6b21b231f4b8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A2-A0YH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7281cb79-aeff-4d05-abcd-2a7a1f048663

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,004; copy number 2: 12,756; copy number 3: 20,871; copy number 4: 9,084; copy number 5: 10,798; copy number 6: 2,105; copy number 7: 316; copy number 11: 139; copy number 12: 283; copy number 13: 466; copy number 14: 817; copy number 18: 19; copy number 19: 24; copy number 21: 41; copy number 25: 91.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A2-A0YH-01A-11D-A107-01): tumor purity 0.43, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,196 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:140,023,749–143,184,435, 163 genes, copy number 11–19 (broad region; genes not listed).
- chr8:35,080,592–40,520,158, 110 genes, copy number 18–25 (broad region; genes not listed).
- chr8:41,261,962–42,897,290, 49 genes, copy number 12–21: SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P.
- chr8:43,125,995–145,066,685, 1,558 genes, copy number 12–14 (broad region; genes not listed).
- chr9:82,744,067–83,713,378, 13 genes, copy number 7: RPS6P12, RASEF, AL499602.1, RN7SKP242, AL137847.3, AL137847.1, FRMD3, AL137847.2, RNU4-29P, RNU4-15P, IDNK, UBQLN1, AL354920.1.
- chr16:10,033,684–14,694,308, 115 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr16:29,350,746–30,822,110, 132 genes, copy number 7 (broad region; genes not listed).
- chr20:15,552,157–15,619,819, 2 genes, copy number 7: AL121584.1, ENSAP1.
- chr20:23,320,958–25,149,372, 54 genes, copy number 7: AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P, LINC01721, AL110503.1, RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1, AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2.

Autosomal genes at a single copy (total copy number 1): 2,004. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
